Gene-level copy-number profile of specimen HCM-BROD-0226-C43-85M from HCMI case HCM-BROD-0226-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 31.1 years (11,364 days).
Specimen HCM-BROD-0226-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09e444e4-5204-4a33-bbfd-2faa34080ff7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0226-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/81d9c49b-1588-458b-99ed-2c7d8f5410d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 49; copy number 2: 22,876; copy number 3: 18,778; copy number 4: 14,403; copy number 5: 1,468; copy number 6: 1,324.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,792 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–522,928, 9 genes, copy number 6: AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene, copy number 6: AC114498.1.
- chr6:60,719,222–61,241,311, 6 genes, copy number 5–6: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1.
- chr8:57,888,975–57,934,329, 1 gene, copy number 5: AC012103.1.
- chr8:66,946,501–67,083,783, 4 genes, copy number 5 (within-gene range 4–5): TCF24, PPP1R42, AC110998.1, COPS5.
- chr8:73,215,929–73,216,627, 1 gene, copy number 5: AC100823.2.
- chr8:75,120,409–75,352,327, 1 gene, copy number 5 (within-gene range 4–5): CASC9.
- chr8:75,302,296–75,302,574, 1 gene, copy number 5: HIGD1AP6.
- chr8:76,162,119–76,308,315, 2 genes, copy number 5: AC011029.1, RNU2-54P.
- chr8:79,259,402–80,484,481, 23 genes, copy number 5: AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P.
- chr8:81,439,436–81,521,818, 4 genes, copy number 5 (within-gene range 4–5): AC018616.1, PMP2, FABP9, FABP4.
- chr8:85,987,323–86,154,225, 2 genes, copy number 5 (within-gene range 4–5): ATP6V0D2, AC023194.1.
- chr8:86,047,109–86,212,236, 3 genes, copy number 5 (within-gene range 4–5): PSKH2, AC023194.3, AC084128.1.
- chr8:89,900,721–89,900,824, 1 gene, copy number 5: RNU6-925P.
- chr20:87,250–64,327,972, 1,401 genes, copy number 5–6 (broad region; genes not listed).
- chr22:15,282,557–18,500,594, 125 genes, copy number 5–6 (broad region; genes not listed).
- chr22:18,873,543–50,801,309, 1,207 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 48. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
